Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3CW, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3CW-01A (Primary Tumor).

10/15/11

ry Case gy Report

Pathology,

DOB:

Sex: F

Physician:

Receiver

Pathologist

Accession:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to , the section "SPECIMEN" may have been added. ****

DIAGNOSIS

(A) RIGHT LOBE AND ISTHMUS WITH RIGHT PARATRACHEAL AND MID-JUGULAR NODE DISSECTION:

PAPILLARY THYROID CARCINOMA.

METASTATIC PAPILLARY CARCINOMA IN 4 OF 6 LYMPH NODES FROM LEVEL 4.

METASTATIC PAPILLARY CARCINOMA IN 10 OF 15 PARATRACHEAL LYMPH NODES.

One perithyroidal lymph node, no tumor present.

Isthmic surgical margin, no tumor present.

Parathyroid gland, one, unremarkable.

ICD-O-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9
10/15/11

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) RIGHT LOBE AND ISTHMUS - A right paratracheal and mid-jugular node dissection (an irregular, pink-red portion of soft tissue 15.0 x 4.5 x 3.0 cm) with a right thyroid lobe (5.0 x 4.0 x 2.0 cm). The specimen is oriented by the surgeon.

A firm, gray-tan, unencapsulated tumor (3.5 x 3.0 x 2.0 cm) is noted in the right thyroid lobe. The tumor appears to be confined to the thyroid. The isthmus margin is taken for frozen section. Multiple lymph nodes are detected from levels 4, 5, and paratracheal areas. The lymph nodes vary in size from 0.2 to 1.5 cm. No abnormalities are identified in the lymph node. Representative sections are submitted in 20 cassettes.

INKING CODE: Black-thyroid.

SECTION CODE: A1, isthmus, margin frozen section; A2-A12, thyroid from superior to inferior; A13-A15, lymph nodes from level 4 (A13, 3 possible lymph nodes; A14, 1 lymph node bisected; A15, 1 possible lymph node; A16, A17, possible lymph nodes from level 5 (A16, 1 possible lymph node and soft tissue; A17, soft tissue); A18-A20, paratracheal lymph node (A18, 8 possible lymph nodes; A19, 6 possible lymph nodes; A20, 1 lymph node bisected).

*FS/DX: NO TUMOR PRESENT.

SNOMED CODES

Source: NCI Genomic Data Commons file cf86f6f3-25f8-4246-999d-684b07063b57 (TCGA-EL-A3CW.18FB3CB9-99FA-4EF9-ABD2-9A8A57C6CC4D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).